Surgical pathology report (de-identified scan), TCGA case TCGA-G7-7501, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-7501-01A (Primary Tumor).

[page 1 of 4]
SPECIMENS:

- A. PARA-AORTIC LYMPH NODE
- B. LEFT KIDNEY
- C. PARA-AORTIC LYMPH NODES

SPECIMEN(S):

- A. PARA-AORTIC LYMPH NODE
- B. LEFT KIDNEY
- C. PARA-AORTIC LYMPH NODES

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Lymph node, paraaortic, biopsy: metastatic carcinoma
Diagnosis was called to [REDACTED]

DIAGNOSIS:

- A. LYMPH NODES, PARA-AORTIC, EXCISION:
- METASTATIC RENAL CELL CARCINOMA (1/1)
- B. KIDNEY, LEFT, RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA (9.5 CM) INVOLVING SINUS ADIPOSE TISSUE
- EXTENSIVE LYMPHOVASCULAR INVOLVEMENT IS IDENTIFIED
- ADRENAL GLAND AND MARGINS OF RESECTION ARE UNINVOLVED
- C. LYMPH NODES, PARA-AORTIC, DISSECTION:
- METASTATIC RENAL CELL CARCINOMA INVOLVING SIX LYMPH NODES (6/11)

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: PARA-AORTIC LYMPH NODE

B: LEFT KIDNEY

C: PARA-AORTIC LYMPH NODES

Specimen Type: Radical nephrectomy

With adrenal gland

Laterality: Left

Tumor Site: Middle pole

Lower pole

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 9.5cm

Additional dimensions: 6.5cm x 3.3cm

Macroscopic Extent of Tumor: Tumor extension into perinephric tissues

WHO CLASSIFICATION

The morphology and immunoprofile below best are not entirely specific but best support a diagnosis of papillary renal carcinoma, type 2. Due to intermediate areas between papillary and clear cell phenotype, a clear papillary renal cell carcinoma was also considered and FISH for TFE gene rearrangement will be performed to exclude an adult translocation related carcinoma. See addendum report.

Histologic Grade (Fuhrman Nuclear Grade):

G3: Nuclei very irregular, approximately 20 u; nucleoli large and prominent

Invasion of Vascular/Lymphatic: Present

Perinephric Tissue Invasion: Present

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Uninvolved by tumor

Regional Lymph Nodes: Positive 7 / 12

Additional Findings: None identified

Pathological Staging (pTNM): pT 3a N 1 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block B4

Population: Tumor Cells

[page 2 of 4]
Stain/Marker:	Result:	Comment:
CYTOKERATIN 7	Negative	
EMA	Negative	Clear cell areas positive
CD 10	Positive	
CYTOKERATIN-HMW-34BE12	Negative	
RACEMACE	Positive	
PAX-2	Positive	
P63	Negative	
HMB 45	Negative	
A103,MELAN-A	Negative	
VIMENTIN	Positive	Focal, weak
RENAL CELL	Positive	
CAM 5.2	Positive	
CYTOKERATIN AE1/3	Positive	
CD 117-C-KIT	Positive	

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the [REDACTED] of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

GROSS DESCRIPTION:

A. PARA-AORTIC LYMPH NODE

Received fresh for intraoperative consultation in a container labeled with the patient's name and designated "para aortic lymph node r/o TCC vs. renal cell" is a 3.1 x 2.2 x 1.6 cm firm, pink-tan lymph node. The specimen is inked black and sectioned to show a tan nodular cut surface. Specimen is entirely submitted as follows:

A1: frozen section material

A2: remaining lymph node

B. LEFT KIDNEY

Received fresh, labeled with the patients name and "left kidney" is an intact kidney with attached perinephric fat measuring 14.9 x 8.3 x 6.2 cm, and weighing 346 grams collectively. The isolated kidney measures 13 x 6.9 x 3.3 cm. Extending from the renal pelvis are a ureter (7 cm in length and 0.3 cm in diameter), renal vein (1.2 cm in length and 0.7 cm in diameter), and renal artery (1.1 cm in diameter and 0.5 cm in diameter). Tumor grossly appears to extend into the ureter and but is not present at the resection margin. There is a 9.5 x 6.5 x 3.3 cm poorly circumscribed, solid to partially cystic, variegated mass with hemorrhage and necrosis in the lower pole involving the cortex, medulla and invading into the renal pelvis. It is adjacent to the renal hilum. The mass grossly appears to invade perinephric fat. The uninvolved renal parenchyma is tan-brown with a well-defined cortico-medullary junction. There is a 4 x 2 x 0.4 cm adrenal gland without focal lesions. No lymph nodes or stones are identified. Gross photographs are taken. Representative sections are submitted as follows:

B1: ureteral margin

B2: vascular margins

B3-B6: tumor closest to capsule

B7-B8: tumor with ureter, shave

B9-B10: tumor with ureter

[page 3 of 4]
[REDACTED]

B11: tumor and perihilar fat
B12: tumor with capsule
B13: tumor with peri-penephric fat
B14: kidney
B15: adrenal
B16-B20: additional sections, tumor with renal pelvis
C. PARAAORTIC LYMPH NODES

Received fresh in a container labeled with the patient's name and designated "paraaortic lymph nodes" is a 7 x 5.5 x 3.2 cm aggregate of red, firm tissue. On section, multiple lymph nodes are identified ranging from 0.2 x 0.2 x 0.1 cm to 5.1 x 3.5 x 2.2 cm. The cut surfaces of the largest lymph nodes are tan and firm. The specimen is submitted as follows:

C1-C5: representative sections, largest lymph node
C6-C8: representative sections, 3 cm lymph node
C9: matted lymph nodes, bisected
C10: matted lymph nodes, bisected
C11: 4 possible lymph nodes
C12: 4 possible lymph nodes

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

ADDENDUM:

ASPCR1-TFE3 Dual Color, Dual Fusion Translocation Probe

Case No

Outside Case No NA

Pathologist

Analytical Interpretation of Results: ASPSCR1/TFE3 translocation negative

Clinical Interpretation of Results:

Translocation involving ASPSCR1 (also known as ASPL) at 17q25 to the transcription factor TFE3 at Xp11.1 was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using a proprietary probe set labeled in the [REDACTED]. Fusion

signals of the ASPSCR1 locus and the TFE3 locus were not identified in this specimen. These results do not exclude a TFE3 translocation in this tumor as such tumors in the kidney can have multiple fusion partners.

Source of case

Block used NA

Tissue fixation formalin-fixed tissue

Tissue source kidney

Limitations

ANALYTE SPECIFIC REAGENT: The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristics determined by the [REDACTED] the. They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Overview of this test

The ASPSCR1-TFE3 Dual Color, Dual Fusion Translocation Probe is designed to detect the juxtaposition of ASPSCR1 (also known as ASPL) to the transcription factor TFE3. Translocation of ASPSCR1 (also known as ASPL) to the transcription factor TFE3, der(17)t(X;17)(p11.2;q25), is characteristic of alveolar soft part sarcoma (ASPS) and present in the majority of cases. The ASPSCR1 PDGFB Dual Color, Dual Fusion Translocation Probe is a mixture of the ASPSCR1 probe

(BAC clones RP11-756O14, RP11-455O6 and RP11-428B22 centromeric of ASPSCR1) labeled with SpectrumGreen and the TFE3 probe labeled with SpectrumOrange (BAC clones RP11-552E4, RP11-344N17 and RP11-753G22 telomeric of TFE3). The expected pattern in a normal nucleus hybridized with the ASPSCR1-TFE3 probe is the two orange, two green signal pattern. In a nucleus harboring the der(17)t(X;17)(p11.2;q25), the most common pattern is one orange signal, one green signal, and one orange/green (yellow) fusion signals resulting from the reciprocal translocation.

[page 4 of 4]
[REDACTED]

This probe was labeled in the [REDACTED] according to the method of [REDACTED]
and
its use is regulated as an ASR [REDACTED]
[REDACTED]

R. Detection of the ASPSCR1-TFE3 gene fusion in paraffin-embedded alveolar soft part sarcomas.

[REDACTED]
Results interpreted yes

Gross Dictation:., [REDACTED]
Microscopic/Diagnostic Dictation:., [REDACTED]
Final Review:., PATHOLOGIST, [REDACTED]
Final Review: PATHOLOGIST, [REDACTED]
Final: PATHOLOGIST, [REDACTED]
Addendum:., Pathologist, [REDACTED]
Addendum Final:., Pathologist, [REDACTED]

Source: NCI Genomic Data Commons file 7179aa85-2998-4619-9500-8d03e7ecdd53 (TCGA-G7-7501.33D1281E-D8D0-4138-84E3-A1C8616EE70C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).